Gene-level copy-number profile of tumor specimen TCGA-61-2610-02A from TCGA case TCGA-61-2610, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 61.5 years (22,481 days).
Specimen TCGA-61-2610-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.a9ad6ed4-b513-48c6-ac3c-334d60dfaf34.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-61-2610-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fd60048d-302d-483a-bc3a-99bc5ec61bdd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 14,763; copy number 2: 34,003; copy number 3: 7,979; copy number 4: 1,340; copy number 5: 1,599; copy number 6: 126.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-61-2610-02A-01D-1134-01): tumor purity 0.87, ploidy 2.01, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:49,121,839–49,188,585, 3 genes: FAM170B-AS1, FAM170B, TMEM273.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,725 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:135,138,469–198,222,513, 1,089 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr5:7,396,138–18,236,196, 192 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:17,224,243–18,307,079, 22 genes, copy number 5: AL136305.1, RBM24, AL034372.1, CAP2, RPL7P26, SUMO2P13, AL138824.1, FAM8A1, NUP153, RNU6-190P, AL138724.1, RNA5SP204, Y_RNA, KIF13A, AL023807.1, NHLRC1, TPMT, KDM1B, DEK, Y_RNA, AL138825.1, RNU6-263P.
- chr8:118,189,455–131,040,909, 197 genes, copy number 5–6 (broad region; genes not listed).
- chr8:135,859,369–145,066,685, 225 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 14,763. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
